Somatic mutation profile of tumor specimen TCGA-VQ-A924-01A (aliquot TCGA-VQ-A924-01A-11D-A410-08) from TCGA case TCGA-VQ-A924, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 69.4 years (25,351 days).
Specimen TCGA-VQ-A924-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86ccca45-1d5e-433c-a2a7-541f837dd0a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A924-10A (Blood Derived Normal), aliquot TCGA-VQ-A924-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a040b96d-1f09-4e15-b3ac-fa08322a88b1

The open-access MAF lists 1,577 somatic variants for this specimen: 1,232 protein-altering or splice-affecting, 312 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 729, Frame Shift Del 372, Silent 312, Frame Shift Ins 65, Nonsense Mutation 38, Splice Site 13, Intron 12, RNA 9, In Frame Del 7, 3'UTR 7, Splice Region 5, 5'Flank 3.

Variants (750 of 1,577; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- AGT | c.1290del p.F430Lfs*25 | Frame Shift Del (DEL) | VAF 34/66 reads (52%) | catalogued as rs387906578, CD065661; ClinVar: pathogenic; called by mutect2, varscan2
- AHI1 | c.910dup p.T304Nfs*6 | Frame Shift Ins (INS) | VAF 20/62 reads (32%) | catalogued as rs753874898; ClinVar: pathogenic; called by mutect2, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ATP6V1B1 | c.1155dup p.I386Hfs*56 | Frame Shift Ins (INS) | VAF 25/80 reads (31%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, varscan2
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- BMPR2 | c.1371del p.K457Nfs*17 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs1085307340; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DYSF | c.4200dup p.I1401Hfs*8 | Frame Shift Ins (INS) | VAF 13/50 reads (26%) | catalogued as rs398123786; ClinVar: pathogenic; called by mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 33/131 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GAA | c.258del p.N87Tfs*55 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs761317813; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- GALK1 | c.410del p.G137Vfs*27 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs767329054, CD993840; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- ITGB4 | c.600dup p.F201Lfs*15 | Frame Shift Ins (INS) | VAF 12/54 reads (22%) | catalogued as rs752657203; ClinVar: pathogenic; called by mutect2, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KMT2A | c.2318del p.P773Rfs*8 | Frame Shift Del (DEL) | VAF 35/125 reads (28%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 34/110 reads (31%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.5104C>T p.R1702* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as rs886043414, COSV56407907; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRIT1 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as rs374662170; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LTBP3 | c.2216del p.G739Afs*7 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | catalogued as rs752375653, CD153951; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MPZ | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs863225025, CM113755, CM139825, CM1412645, COSV100337787; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 41/87 reads (47%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PARN | c.1257dup p.N420* | Frame Shift Ins (INS) | VAF 15/49 reads (31%) | catalogued as rs942538351; ClinVar: pathogenic; called by mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as rs1562671039, COSV99763719; ClinVar: pathogenic; called by muse, varscan2
- RYR1 | c.3801del p.C1268Afs*4 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs587784374; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SPG7 | c.1032del p.G345Afs*87 (on ENST00000268704; = p.G352Afs*87 on NM_003119.4) | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs760818649; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A1BG | c.382T>C p.W128R | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1302662626, COSV99568067; called by muse, mutect2, varscan2
- AADAC | c.356G>A p.S119N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV99233004; called by muse, mutect2, varscan2
- AASS | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as COSV100741609; called by muse, mutect2, varscan2
- ABCA2 | c.2839G>A p.V947M (on ENST00000614293; = p.V917M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99686622; called by muse, mutect2, varscan2
- ABCA4 | c.6799G>A p.A2267T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV100932995; called by muse, mutect2, varscan2
- ABCA5 | c.3234del p.F1078Lfs*6 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | catalogued as COSV67016962; called by mutect2, pindel, varscan2
- ABCC1 | c.2509G>A p.V837I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs754975789, COSV100578120; called by muse, mutect2, varscan2
- ABCC4 | c.2365G>A p.V789I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs779403637, COSV65315057; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC9 | c.4516C>A p.R1506S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99683967; called by muse, mutect2, varscan2
- ABCD1 | c.1651G>T p.G551C | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99497133; called by muse, mutect2, varscan2
- ABCG4 | c.1167G>A p.T389= | Splice Region (SNP) | VAF 54/190 reads (28%) | catalogued as rs905395186, COSV100266403, COSV56642266; called by muse, mutect2, varscan2
- ABLIM2 | c.1649C>T p.P550L (on ENST00000341937 / NM_001130084.2; = p.P460L on NM_032432.5) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1560406036, COSV56400932; called by muse, mutect2, varscan2
- AC023055.1 | c.1451A>G p.D484G | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1256066451, COSV100278373; called by muse, mutect2, varscan2
- AC093525.2 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | PolyPhen benign (0.003); catalogued as rs1476986826, COSV99565477; called by muse, mutect2, varscan2
- AC109583.1 | c.241A>T p.T81S | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100167741; called by muse, mutect2, varscan2
- AC126283.2 | c.875G>A p.G292D | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV101143974; called by muse, mutect2, varscan2
- AC127029.3 | c.428C>A p.A143D | Missense Mutation (SNP) | VAF 77/274 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs1207943996, COSV100033134; called by muse, mutect2, varscan2
- ACAA1 | c.368G>A p.C123Y | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100085663; called by muse, mutect2, varscan2
- ACIN1 | c.3968G>A p.R1323H | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs761845612, COSV52973884; called by muse, mutect2, varscan2
- ACO2 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.342); catalogued as rs955494552, COSV99346917; called by muse, mutect2, varscan2
- ACSBG1 | c.59A>T p.D20V | Missense Mutation (SNP) | VAF 83/293 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV99356898; called by muse, mutect2, varscan2
- ACSL4 | c.2095C>A p.H699N (on ENST00000340800 / NM_022977.2; = p.H658N on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as rs898008437, COSV100538220; called by muse, mutect2, varscan2
- ACSM4 | c.1301A>T p.K434I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.088); catalogued as COSV101256926; called by muse, mutect2, varscan2
- ACTB | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV100079288; called by muse, mutect2, varscan2
- ACTR3 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs200071930, COSV99603263; called by muse, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS18 | c.3035G>T p.R1012M | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); catalogued as COSV99270800; called by muse, mutect2, varscan2
- ADAMTS18 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 81/291 reads (28%) | catalogued as rs191773926, COSV51425210; called by muse, mutect2, varscan2
- ADAMTS5 | c.1728G>T p.W576C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99536845; called by muse, mutect2, varscan2
- ADAMTS7 | c.5044C>T p.R1682W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764163081, COSV66309621; called by muse, varscan2
- ADAT2 | c.115A>G p.N39D | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.078); catalogued as COSV99395548; called by muse, mutect2, varscan2
- ADGRB3 | c.647A>G p.N216S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV100999481; called by muse, mutect2, varscan2
- ADGRG5 | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs200866735; called by muse, mutect2, varscan2
- ADGRV1 | c.11747A>G p.H3916R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV101315286; called by muse, mutect2, varscan2
- ADNP2 | c.2221T>C p.W741R | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as rs1445388789, COSV100080454; called by muse, mutect2, varscan2
- AFDN | c.5416A>G p.N1806D (on ENST00000447894 / NM_001366320.1; = p.N1725D on NM_001207008.1) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs771118698, COSV100652272; called by muse, mutect2, varscan2
- AFTPH | c.90A>T p.E30D | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.34); catalogued as COSV99480199; called by muse, mutect2, varscan2
- AGT | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs567719599, COSV100794172; called by muse, mutect2, varscan2
- AHCTF1 | c.4076C>T p.A1359V (on ENST00000366508; = p.A1333V on NM_015446.5) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV100402941; called by muse, mutect2, varscan2
- AHSA1 | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV99375782; called by muse, mutect2, varscan2
- AKAP17A | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs767031850, COSV100001751; called by muse, mutect2, varscan2
- AKAP17A | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as COSV100001754; called by muse, mutect2, varscan2
- AKAP4 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.324); catalogued as COSV100654118; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as COSV62339755; called by mutect2, varscan2
- AL441992.2 | c.1249C>A p.L417I | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV100223305; called by muse, mutect2, varscan2
- ALDH18A1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100973018; called by muse, mutect2, varscan2
- ALDH1L1 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747287426, COSV56413750; called by muse, mutect2, varscan2
- ALMS1 | c.3080T>C p.L1027P | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100040761; called by muse, mutect2, varscan2
- ALPG | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs1279045240, COSV99779097; called by muse, mutect2, varscan2
- AMOTL1 | c.112T>C p.F38L | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100133587; called by muse, mutect2, varscan2
- ANK1 | c.2842C>T p.R948C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749623248, COSV55889703, COSV99225589; called by muse, varscan2
- ANK1 | c.2764C>T p.R922W | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1478581881, COSV55872922; called by muse, varscan2
- ANKFY1 | c.3256G>A p.A1086T (on ENST00000341657 / NM_001330063.2; = p.A1087T on NM_016376.5) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs757442296, COSV100492132; called by muse, mutect2, varscan2
- ANKRD11 | c.4840C>T p.R1614W | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1170699512, COSV99967929; called by muse, mutect2, varscan2
- ANKRD53 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.868); catalogued as rs187992279, COSV99721180; called by muse, mutect2, varscan2
- ANKS6 | c.1804G>A p.G602S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779868836, COSV100782207; called by muse, mutect2, varscan2
- ANXA11 | c.901T>A p.S301T | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.998); catalogued as COSV99626670; called by muse, mutect2, varscan2
- AP1M2 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99140705; called by muse, mutect2
- AP4E1 | c.260G>A p.C87Y | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99956148; called by muse, mutect2, varscan2
- AP5Z1 | c.2086dup p.Q696Pfs*67 | Frame Shift Ins (INS) | VAF 6/21 reads (29%) | catalogued as rs771683676; called by mutect2, varscan2
- APH1B | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs551566250, COSV56013895; called by muse, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs546686089; called by mutect2, varscan2
- APOBEC3F | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0.014); catalogued as rs143540233, COSV57911905; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs749401724; called by mutect2, varscan2
- ARAP3 | c.3848G>A p.R1283H | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758532450, COSV99499186; called by muse, mutect2, varscan2
- ARCN1 | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50614669; called by muse, mutect2, varscan2
- ARHGEF1 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1555847372, COSV100528805; called by muse, mutect2, varscan2
- ARHGEF10 | c.3707G>A p.G1236D (on ENST00000398564; = p.G1211D on NM_014629.4) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100033372; called by muse, mutect2, varscan2
- ARHGEF11 | c.3232del p.V1078Cfs*35 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | catalogued as COSV100168158; called by mutect2, pindel, varscan2
- ARHGEF17 | c.2365G>T p.G789C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV99734695; called by muse, mutect2, varscan2
- ARID1A | c.2318C>T p.P773L | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs373690941; called by muse, mutect2, varscan2
- ARID3A | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs145361495; called by muse, mutect2, varscan2
- ARIH1 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV101158509; called by muse, mutect2, varscan2
- ARL10 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751942928, COSV100118920; called by muse, mutect2, varscan2
- ARNT2 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs144530385, COSV100308811; called by muse, mutect2, varscan2
- ARRDC1 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs146599172; called by muse, mutect2, varscan2
- ARSJ | c.1736dup p.K580Efs*32 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs753865255; called by mutect2, varscan2
- ARSL | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1054544689, COSV101140334; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASB1 | c.487C>A p.L163I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99223067; called by muse, mutect2, varscan2
- ASB17 | c.533del p.P178Lfs*6 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as COSV99407822; called by mutect2, pindel, varscan2
- ASCC3 | c.6358G>T p.G2120* | Nonsense Mutation (SNP) | VAF 60/234 reads (26%) | catalogued as COSV100976134; called by muse, mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | catalogued as rs747570359; called by mutect2, varscan2
- ASTN2 | c.2929T>C p.C977R (on ENST00000313400 / NM_001365069.1; = p.C926R on NM_014010.5) | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99939961; called by muse, mutect2, varscan2
- ATP10A | c.3614C>T p.T1205I | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as COSV100790718; called by muse, mutect2, varscan2
- ATP10A | c.2880del p.S961Pfs*13 | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | catalogued as COSV63515447, COSV63524597; called by mutect2, pindel, varscan2
- ATP11A | c.1093T>C p.Y365H | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99367105; called by muse, mutect2, varscan2
- ATP13A3 | c.3079del p.W1027Gfs*31 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as rs746602775; called by mutect2, varscan2
- ATP8B1 | c.241A>G p.N81D | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99376669; called by muse, mutect2, varscan2
- ATP9B | c.1526T>C p.M509T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100302591; called by mutect2, varscan2
- ATXN1 | c.1951T>C p.F651L | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99784505; called by muse, mutect2, varscan2
- ATXN2L | c.2062del p.R688Gfs*11 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | catalogued as COSV57377219; called by mutect2, pindel, varscan2
- AVEN | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as COSV100145173; called by muse, mutect2, varscan2
- B3GALT5 | c.74T>C p.M25T | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as rs545552313, COSV100563230; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs35951843; called by mutect2, pindel, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 19/91 reads (21%) | catalogued as rs745882580; called by mutect2, varscan2
- BAZ2B | c.2587A>G p.R863G | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.304); catalogued as COSV100600250; called by muse, mutect2, varscan2
- BBX | c.1289G>A p.C430Y | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV100360766; called by muse, mutect2, varscan2
- BCAM | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs774225592, COSV54301864; called by muse, mutect2, varscan2
- BCL11B | c.1259C>T p.P420L (on ENST00000357195 / NM_001282237.2; = p.P349L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs770601161, COSV100595022; called by muse, varscan2
- BCL2L13 | c.519A>C p.E173D | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as COSV100456095; called by muse, mutect2, varscan2
- BCL6 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as rs372638471, COSV51654854; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs768244116; called by mutect2, pindel
- BCS1L | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as rs1197613485, CM1312752, COSV99828771; called by muse, mutect2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs752427670; called by mutect2, varscan2
- BEGAIN | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs140676218; called by muse, mutect2, varscan2
- BEND5 | c.1052del p.K351Rfs*15 | Frame Shift Del (DEL) | VAF 29/109 reads (27%) | catalogued as rs756345162, COSV65718189; called by mutect2, varscan2
- BFSP2 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100183418; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.573T>G p.I191M | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.79); catalogued as COSV99958448; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BMS1 | c.920T>C p.V307A | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV100996394; called by muse, mutect2, varscan2
- BPTF | c.8818C>A p.L2940I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.593); catalogued as COSV100073607; called by muse, mutect2, varscan2
- BRPF3 | c.2642A>G p.E881G | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100325490; called by muse, mutect2, varscan2
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | catalogued as rs746043904; called by mutect2, varscan2
- BSN | c.4655A>G p.Q1552R | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99606891; called by muse, mutect2, varscan2
- BTBD11 | c.2731C>T p.R911C (on ENST00000280758 / NM_001018072.2; = p.R448C on NM_001017523.2) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759539484, COSV55039504; called by muse, mutect2, varscan2
- C11orf80 | c.438C>A p.S146R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV100690627; called by muse, mutect2, varscan2
- C1orf105 | c.487C>A p.L163I | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV100877898; called by muse, mutect2, varscan2
- C1orf112 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199972566; called by muse, mutect2, varscan2
- C2orf16 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs1159281670, COSV62677328, COSV99051903; called by muse, mutect2, varscan2
- C3 | c.2670del p.K891Sfs*13 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | catalogued as rs750770711, COSV99837243; called by mutect2, pindel, varscan2
- C4orf50 | c.445G>T p.A149S (on ENST00000324058; = p.A1381S on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV100135463, COSV100135885; called by muse, mutect2, varscan2
- C6 | c.828del p.S277Afs*43 | Frame Shift Del (DEL) | VAF 18/81 reads (22%) | catalogued as rs372345940, CD982526, COSV54718324; called by mutect2, pindel, varscan2
- CACNA1H | c.6964C>T p.R2322W | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs987712309, COSV52353215; called by muse, mutect2, varscan2
- CAMTA1 | c.4132C>T p.R1378C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs374903153, COSV100345150; called by muse, mutect2, varscan2
- CAPN11 | c.1220del p.G407Afs*42 | Frame Shift Del (DEL) | VAF 30/142 reads (21%) | catalogued as rs1254054225; called by pindel, varscan2
- CARD9 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs747925378, COSV53734822; called by muse, mutect2, varscan2
- CASD1 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99802087; called by muse, mutect2, varscan2
- CATSPER3 | c.198del p.F66Lfs*10 | Frame Shift Del (DEL) | VAF 43/149 reads (29%) | catalogued as CM110786; called by mutect2, pindel, varscan2
- CATSPERB | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as rs774967902, COSV99830670; called by muse, mutect2, varscan2
- CBLC | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs147316311; called by muse, mutect2, varscan2
- CCDC102B | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV100101625; called by muse, mutect2, varscan2
- CCDC174 | c.286dup p.M96Nfs*3 | Frame Shift Ins (INS) | VAF 13/50 reads (26%) | catalogued as rs763143298; called by mutect2, pindel, varscan2
- CCDC51 | c.979C>A p.L327I | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV99602002; called by muse, mutect2, varscan2
- CCDC62 | c.1280T>C p.L427S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV99456452; called by muse, mutect2, varscan2
- CCDC73 | c.1222T>C p.S408P | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV100066083; called by muse, mutect2, varscan2
- CCDC78 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99284469, COSV99284586; called by muse, mutect2, varscan2
- CCDC91 | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs760444503, COSV60339920; called by muse, mutect2, varscan2
- CCDC96 | c.887A>C p.K296T | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.106); catalogued as COSV100027730; called by muse, mutect2, varscan2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | catalogued as rs765438623; called by mutect2, pindel, varscan2
- CCER1 | c.287del p.P96Lfs*39 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs1190639826; called by mutect2, pindel, varscan2
- CCNA2 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV99696645; called by muse, mutect2, varscan2
- CCNB2 | c.1109G>A p.S370N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs1269283031, COSV99878869; called by muse, mutect2, varscan2
- CD109 | c.2786T>G p.F929C | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99752269; called by muse, mutect2, varscan2
- CD163L1 | c.3241G>A p.V1081M | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.257); catalogued as COSV100549484; called by muse, mutect2, varscan2
- CD200R1 | c.961G>T p.D321Y (on ENST00000471858 / NM_170780.3; = p.D344Y on NM_138806.4) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV99866621, COSV99867677; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CDC27 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs201098929; called by mutect2, varscan2
- CDC42BPB | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV63475296; called by muse, mutect2, varscan2
- CDH1 | c.455A>G p.Q152R | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.014); catalogued as rs1233421331, COSV99930997; called by muse, mutect2, varscan2
- CDH10 | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.242); catalogued as COSV100049577; called by muse, mutect2, varscan2
- CDH10 | c.526G>T p.G176C | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100049578; called by muse, mutect2, varscan2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | catalogued as rs752398646; called by mutect2, pindel, varscan2
- CDH6 | c.1926del p.E643Sfs*3 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | catalogued as rs1561075636; called by mutect2, pindel, varscan2
- CDH8 | c.1168G>A p.V390I | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as rs372648256; called by muse, mutect2, varscan2
- CDHR2 | c.1147dup p.R383Pfs*6 | Frame Shift Ins (INS) | VAF 17/78 reads (22%) | catalogued as rs774414740; called by mutect2, pindel, varscan2
- CDKL4 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs767353955, COSV101115055; called by muse, mutect2, varscan2
- CEL | c.2255C>T p.A752V (on ENST00000673714; = p.A749V on NM_001807.6) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1164412150, COSV100672141; called by muse, mutect2, varscan2
- CENPB | c.220T>C p.Y74H | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.273); catalogued as COSV100713206; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs1325731082; called by mutect2, varscan2
- CENPE | c.2628G>T p.Q876H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV99476676; called by mutect2, varscan2
- CENPH | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as rs757244178, COSV99295434; called by muse, varscan2
- CENPT | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs779684299, COSV54650304, COSV54650752, COSV99535160; called by muse, mutect2, varscan2
- CEP126 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.063); catalogued as COSV99680399; called by muse, mutect2, varscan2
- CERCAM | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.195); catalogued as rs767136791, COSV100863784, COSV100864127; called by muse, mutect2, varscan2
- CFAP53 | c.298A>C p.K100Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV101274928; called by muse, varscan2
- CHD7 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV101417929; called by muse, mutect2, varscan2
- CHL1 | c.911A>G p.D304G (on ENST00000397491 / NM_001253387.1; = p.D320G on NM_006614.4) | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849673; called by muse, mutect2, varscan2
- CHPF | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs773984489, COSV60534570; called by muse, mutect2, varscan2
- CHST12 | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.338); catalogued as COSV99324203; called by muse, mutect2, varscan2
- CIT | c.4067G>A p.R1356H | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774914678, COSV55863025, COSV99949497; called by muse, mutect2, varscan2
- CLCN3 | c.2270T>C p.M757T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV100641549; called by muse, mutect2, varscan2
- CLEC12A | c.61dup p.I21Nfs*63 | Frame Shift Ins (INS) | VAF 8/55 reads (15%) | catalogued as rs766312863; called by mutect2, pindel, varscan2
- CLIC5 | c.983A>G p.K328R (on ENST00000185206 / NM_001370649.1; = p.K169R on NM_016929.5) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV99483509; called by muse, mutect2, varscan2
- CLK2 | c.1438G>A p.A480T (on ENST00000368361 / NM_001294339.2; = p.A479T on NM_003993.4) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs746962823, COSV56943919; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 22/108 reads (20%) | catalogued as rs369752219; called by mutect2, varscan2
- CLOCK | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59402496; called by muse, mutect2
- CLSPN | c.2407G>T p.A803S | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV99230088; called by muse, mutect2, varscan2
- CLTCL1 | c.3920T>C p.L1307P | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99594326; called by mutect2, varscan2
- CNKSR1 | c.1535dup p.P513Tfs*9 (on ENST00000374253 / NM_001297647.2; = p.P506Tfs*9 on NM_006314.3) | Frame Shift Ins (INS) | VAF 10/45 reads (22%) | catalogued as rs753922055; called by mutect2, varscan2
- CNKSR2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV54252151; called by muse, mutect2, varscan2
- CNN1 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99372155; called by muse, mutect2, varscan2
- CNTN3 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99722850; called by muse, mutect2, varscan2
- CNTN4 | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101281093; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV100661545; called by muse, mutect2, varscan2
- CNTNAP4 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV100268869; called by muse, mutect2, varscan2
- CNTNAP4 | c.2458T>C p.F820L | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV56681724; called by muse, mutect2, varscan2
- COCH | c.1049C>T p.A350V (on ENST00000216361 / NM_001347720.1; = p.A285V on NM_004086.3) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV99363297; called by muse, mutect2, varscan2
- COG7 | c.2270G>A p.R757H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs368733148, COSV100207295; called by muse, mutect2, varscan2
- COL12A1 | c.3662T>C p.F1221S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV100485110; called by muse, mutect2, varscan2
- COL13A1 | c.2134C>A p.Q712K (on ENST00000398978 / NM_001130103.2; = p.Q640K on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.949); catalogued as COSV100637212; called by muse, mutect2, varscan2
- COL5A1 | c.1762G>A p.V588M | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs918680618, COSV100879291; called by muse, mutect2
- COL5A1 | c.3561del p.I1188Sfs*88 | Frame Shift Del (DEL) | VAF 34/142 reads (24%) | catalogued as rs1564474840; called by pindel, varscan2
- COL5A2 | c.4378A>G p.T1460A | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100879879; called by muse, mutect2, varscan2
- COL6A3 | c.5311del p.V1771Sfs*8 | Frame Shift Del (DEL) | VAF 19/82 reads (23%) | catalogued as COSV55082747; called by mutect2, pindel, varscan2
- COL9A1 | c.740C>A p.P247H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100293641; called by muse, mutect2, varscan2
- CPNE7 | c.1594A>G p.I532V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.669); catalogued as rs770891842, COSV99254436; called by muse, mutect2, varscan2
- CPNE8 | c.1553T>C p.L518P | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs893133843, COSV100503652; called by muse, mutect2, varscan2
- CPTP | c.123-1G>T p.X41_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100027845; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 34/135 reads (25%) | catalogued as rs747832403; called by mutect2, varscan2
- CRACD | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1287374834, COSV99948315; called by muse, mutect2, varscan2
- CREB3L1 | c.823T>C p.Y275H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99914732; called by muse, mutect2
- CRELD1 | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV99926224; called by muse, mutect2
- CRYBB1 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.025); catalogued as COSV99315787; called by muse, mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 42/140 reads (30%) | catalogued as rs762650691; called by mutect2, pindel, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | catalogued as rs747437399; called by mutect2, pindel, varscan2
- CSMD1 | c.2633G>A p.G878D (on ENST00000520002; = p.G877D on NM_033225.6) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59394616; called by muse, mutect2
- CSPG4 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.437); catalogued as COSV100413200; called by muse, mutect2, varscan2
- CST4 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 30/145 reads (21%) | catalogued as rs767756120; called by mutect2, varscan2
- CSTF3 | c.613del p.M205* | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs1300471016; called by mutect2, pindel
- CUBN | c.1845T>G p.D615E | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100911815; called by muse, mutect2, varscan2
- CUBN | c.1175G>C p.C392S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1329209040, COSV100911816, COSV64710896; called by muse, mutect2, varscan2
- CUX1 | c.1289dup p.P431Sfs*16 | Frame Shift Ins (INS) | VAF 24/78 reads (31%) | catalogued as rs782381199; called by mutect2, varscan2
- DAAM1 | c.3004C>T p.R1002C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773103520, COSV62840382; called by muse, mutect2, varscan2
- DAO | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs373110648; called by muse, mutect2
- DAPK1 | c.3454C>A p.L1152M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100800676, COSV63788406; called by muse, mutect2, varscan2
- DCAF12L2 | c.758T>C p.I253T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV100758410; called by muse, mutect2, varscan2
- DCAF8L1 | c.598A>G p.S200G | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV101491366; called by muse, mutect2, varscan2
- DCAKD | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as rs760851820, COSV100149388; called by muse, mutect2, varscan2
- DCP1B | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV99767063; called by muse, mutect2, varscan2
- DDIAS | c.2614dup p.I872Nfs*25 | Frame Shift Ins (INS) | VAF 14/71 reads (20%) | catalogued as rs1190388546; called by mutect2, pindel, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX39A | c.330C>G p.N110K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.112); catalogued as rs369555390, COSV99660067; called by muse, mutect2, varscan2
- DDX53 | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV100028606; called by muse, mutect2, varscan2
- DEFB116 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1460804408, COSV101269195; called by muse, mutect2, varscan2
- DENND2D | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.615); catalogued as rs145056723; called by muse, mutect2, varscan2
- DENND3 | c.1796C>T p.T599M | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs144554854; called by muse, varscan2
- DENND5B | c.2453A>G p.H818R | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100170676; called by muse, mutect2, varscan2
- DHX9 | c.2341C>T p.R781C | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100841186; called by muse, mutect2, varscan2
- DHX9 | c.3502G>A p.D1168N | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV100841188; called by muse, mutect2, varscan2
- DIAPH3 | c.2125del p.I709Lfs*7 (on ENST00000400324 / NM_001042517.2; = p.I446Lfs*7 on NM_030932.3) | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs777749882, COSV99934632; called by mutect2, pindel, varscan2
- DLG4 | c.1580C>T p.T527M (on ENST00000399506 / NM_001321075.3; = p.T570M on NM_001365.4) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as rs1220391805, COSV100263329; called by muse, mutect2, varscan2
- DMRTB1 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437493361, COSV65113028, COSV65113762; called by muse, mutect2
- DNAH2 | c.1418A>T p.N473I | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV99317772; called by muse, mutect2
- DNAH3 | c.11774C>T p.A3925V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.243); catalogued as COSV99764214; called by muse, mutect2, varscan2
- DNAH7 | c.5135A>G p.K1712R | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100413325; called by muse, mutect2, varscan2
- DNAH8 | c.4418del p.N1473Ifs*15 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as rs778628413, COSV59486260; called by mutect2, varscan2
- DNAI4 | c.89del p.K30Rfs*28 | Frame Shift Del (DEL) | VAF 33/123 reads (27%) | catalogued as rs774662919; called by mutect2, pindel, varscan2
- DNAJC19 | c.272C>A p.P91H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100699991; called by muse, mutect2, varscan2
- DNMT1 | c.4132C>T p.R1378W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61578541; called by muse, mutect2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 30/58 reads (52%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK5 | c.1735del p.M579Wfs*8 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | catalogued as rs1282784562; called by mutect2, pindel, varscan2
- DOCK5 | c.4633del p.H1545Tfs*45 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as COSV52406390; called by mutect2, pindel, varscan2
- DOCK6 | c.5485T>C p.F1829L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as COSV99624356; called by muse, mutect2, varscan2
- DOP1A | c.6811T>C p.S2271P | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV99380581; called by muse, mutect2, varscan2
- DOT1L | c.4066C>T p.Q1356* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as COSV101288472; called by muse, mutect2, varscan2
- DPYD | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100928349; called by muse, mutect2, varscan2
- DPYSL3 | c.810del p.G271Efs*3 | Frame Shift Del (DEL) | VAF 50/171 reads (29%) | catalogued as COSV58330462; called by mutect2, pindel, varscan2
- DRD5 | c.1040T>C p.F347S | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV100431449; called by muse, mutect2, varscan2
- DROSHA | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100757413, COSV100757561; called by muse, mutect2, varscan2
- DSP | c.4423A>C p.T1475P | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV101131152; called by muse, mutect2, varscan2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as rs762133243; called by mutect2, pindel, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | catalogued as rs772082432; called by mutect2, varscan2
- DYRK1A | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.973); catalogued as rs757222616, COSV58703632; called by muse, mutect2, varscan2
- DYRK2 | c.682A>G p.I228V (on ENST00000344096 / NM_006482.3; = p.I155V on NM_003583.4) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV100165153; called by muse, mutect2, varscan2
- EDEM3 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771252507, COSV58926021, COSV58926423; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs753591380, COSV100668268; called by muse, mutect2, varscan2
- EHD2 | c.1495G>T p.G499C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99621487, COSV99622288; called by muse, mutect2, varscan2
- EIF2S1 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99370693; called by muse, mutect2, varscan2
- EIF3B | c.943C>A p.R315S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV100703484, COSV62804598; called by muse, mutect2, varscan2
- EIF4G3 | c.1069A>G p.N357D | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.265); catalogued as COSV99942800; called by muse, mutect2, varscan2
- EIF5B | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99176729; called by muse, mutect2, varscan2
- ELK3 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.939); catalogued as rs781432909, COSV99957435; called by muse, mutect2, varscan2
- ELL2 | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV52983182, COSV52983409; called by muse, mutect2, varscan2
- ELOA | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 25/115 reads (22%) | catalogued as COSV101403564, COSV69309476; called by muse, mutect2, varscan2
- EMC2 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99623787; called by muse, mutect2, varscan2
- EMILIN1 | c.1353del p.L452Cfs*5 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as COSV53155402; called by mutect2, varscan2
- ENTPD7 | c.208G>T p.G70W | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV100978325; called by muse, mutect2, varscan2
- EPB41L1 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99148723; called by muse, mutect2
- EPSTI1 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771486075, COSV58048113; called by muse, mutect2, varscan2
- ERBB3 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0.049); catalogued as COSV57265535, COSV99915383; called by muse, mutect2, varscan2
- ESPL1 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99228666; called by muse, mutect2, varscan2
- ESPL1 | c.3874T>C p.W1292R | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99228668; called by muse, mutect2, varscan2
- ETV5 | c.421del p.L141Sfs*66 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as COSV100112607; called by mutect2, varscan2
- EVC | c.1652del p.P551Rfs*7 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | catalogued as rs1312383000; called by mutect2, pindel, varscan2
- EVI2B | c.593del p.N198Tfs*6 | Frame Shift Del (DEL) | VAF 41/119 reads (34%) | catalogued as rs765136869; called by mutect2, pindel, varscan2
- EXOC3L1 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs775635066, COSV99333329; called by muse, mutect2, varscan2
- FAF1 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs750800804, COSV100875130; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM135A | c.3064G>A p.G1022S (on ENST00000370479 / NM_001351599.1; = p.G809S on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs901985483, COSV99524993; called by muse, mutect2, varscan2
- FAM155B | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.25); PolyPhen benign (0.274); catalogued as rs770211531, COSV52936224, COSV99368068; called by muse, varscan2
- FAM169A | c.1190A>G p.E397G | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100998280; called by muse, mutect2, varscan2
- FAM184A | c.353A>G p.H118R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100137244; called by muse, mutect2, varscan2
- FAM189B | c.1787G>A p.R596K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100516164; called by muse, mutect2, varscan2
- FAM227B | c.1232A>C p.K411T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as COSV100174257; called by muse, mutect2, varscan2
- FAM71B | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs112210804, COSV57228795; called by muse, mutect2, varscan2
- FASN | c.385G>T p.G129C | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100147157; called by muse, mutect2, varscan2
- FAT1 | c.434T>C p.L145S | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101498595; called by muse, mutect2, varscan2
- FAT4 | c.6962G>A p.S2321N | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.258); catalogued as COSV100626831; called by muse, mutect2, varscan2
- FBN2 | c.6440A>G p.D2147G | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99324010; called by muse, mutect2, varscan2
- FBN2 | c.1754T>C p.L585P | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV99324012; called by muse, mutect2, varscan2
- FBXO38 | c.1025T>C p.M342T | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV99692999; called by muse, mutect2, varscan2
- FBXO44 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs750135661, COSV99278685; called by muse, mutect2, varscan2
- FBXW4 | c.1262G>A p.C421Y | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.159); catalogued as rs1420087169, COSV100489312; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 40/106 reads (38%) | catalogued as rs748969702; called by mutect2, varscan2
- FFAR2 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99875931; called by muse, mutect2, varscan2
- FFAR3 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as rs544946440, COSV59908723; called by muse, mutect2, varscan2
- FGF2 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV99144541; called by muse, mutect2, varscan2
- FGFR1OP2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1169395956, COSV99986788; called by muse, mutect2, varscan2
- FIGN | c.2246T>A p.V749D | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100291216; called by muse, mutect2, varscan2
- FKBP11 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as rs537059154, COSV99872641; called by muse, mutect2, varscan2
- FKBPL | c.880del p.V294Lfs*22 | Frame Shift Del (DEL) | VAF 30/128 reads (23%) | catalogued as rs757166166; called by mutect2, pindel, varscan2
- FLNC | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV100367470; called by muse, mutect2, varscan2
- FNDC7 | c.2009G>A p.C670Y | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99600799; called by muse, mutect2, varscan2
- FOXD4L5 | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.18); catalogued as COSV66240030; called by mutect2, varscan2
- FOXK1 | c.1245G>A p.R415= | Splice Region (SNP) | VAF 22/82 reads (27%) | catalogued as rs899011992, COSV100194449; called by muse, mutect2, varscan2
- FOXO3 | c.723del p.K242Rfs*117 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | catalogued as COSV59631234; called by mutect2, pindel, varscan2
- FOXRED1 | c.99G>T p.K33N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99702428; called by muse, mutect2, varscan2
- FOXRED2 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143739893; called by muse, mutect2, varscan2
- FREM1 | c.2264A>C p.N755T | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101083544; called by muse, mutect2, varscan2
- FRG2C | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.644); catalogued as rs1179297288; called by muse, mutect2, varscan2
- FRMPD2 | c.284A>G p.E95G | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100563394; called by muse, mutect2, varscan2
- FSHB | c.160-2A>G p.X54_splice | Splice Site (SNP) | VAF 15/57 reads (26%) | catalogued as COSV99569274; called by muse, varscan2
- FSHB | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99569276; called by muse, varscan2
- FSTL4 | c.2369del p.G790Vfs*6 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | catalogued as rs765771244; called by mutect2, pindel, varscan2
- FSTL5 | c.1535A>C p.K512T | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV100051504, COSV60188329; called by muse, mutect2, varscan2
- FUT7 | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779657024, COSV99686625; called by muse, mutect2, varscan2
- FZD10 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); catalogued as COSV57473058; called by muse, mutect2, varscan2
- GABRA5 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as rs368128930, COSV59477680; called by muse, mutect2, varscan2
- GAN | c.358C>A p.L120M | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV101633949; called by muse, mutect2, varscan2
- GAS2L2 | c.1226del p.P409Lfs*92 | Frame Shift Del (DEL) | VAF 26/113 reads (23%) | catalogued as rs782212939; called by pindel, varscan2
- GASK1B | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1478780697, COSV99647137; called by muse, mutect2, varscan2
- GCN1 | c.3060del p.N1021Tfs*24 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as COSV56104456; called by mutect2, pindel, varscan2
- GEM | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.717); catalogued as rs145789382, COSV52597934; called by muse, mutect2, varscan2
- GEMIN6 | c.245T>G p.L82R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99931526; called by muse, mutect2, varscan2
- GFRAL | c.173G>A p.C58Y | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100474294; called by muse, mutect2, varscan2
- GHSR | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99576606; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | catalogued as rs750227570; called by mutect2, varscan2
- GJD2 | c.705del p.C236Afs*19 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as COSV51749244; called by mutect2, pindel, varscan2
- GLDN | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764239923, COSV100117380; called by muse, mutect2, varscan2
- GLG1 | c.2053-1G>T p.X685_splice | Splice Site (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99215114; called by muse, mutect2, varscan2
- GLI2 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.02); catalogued as COSV100082011; called by muse, mutect2, varscan2
- GLIS2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.121); catalogued as rs372555307; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as rs749150409; called by mutect2, varscan2
- GNA14 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV100502399; called by muse, mutect2, varscan2
- GNAT1 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99222222; called by muse, mutect2, varscan2
- GOLPH3 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as rs374757542; called by muse, mutect2, varscan2
- GOLT1A | c.221del p.G74Vfs*64 | Frame Shift Del (DEL) | VAF 37/130 reads (28%) | catalogued as rs765260894; called by mutect2, pindel, varscan2
- GPALPP1 | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100689076; called by muse, mutect2, varscan2
- GPR149 | c.341G>T p.C114F | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101078007; called by muse, mutect2, varscan2
- GPR182 | c.728G>A p.C243Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1222044941, COSV100267610; called by muse, mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 36/126 reads (29%) | catalogued as rs1416935976; called by mutect2, varscan2
- GPR35 | c.56T>A p.I19N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100166237; called by muse, mutect2, varscan2
- GPS1 | c.610A>G p.N204D | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV100135781; called by muse, mutect2, varscan2
- GRAMD1A | c.1738G>A p.G580S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs557938407, COSV100526507, COSV58767226; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIN3A | c.2707C>T p.L903F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100701309; called by muse, mutect2, varscan2
- GRINA | c.775G>T p.G259C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100507190; called by muse, mutect2, varscan2
- GRK2 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765668445, COSV100419529; called by muse, mutect2, varscan2
- GRM1 | c.2254G>A p.G752S | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV51108842, COSV51109512; called by muse, mutect2, varscan2
- GRM3 | c.579del p.D194Tfs*23 | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | catalogued as rs1470079689; called by mutect2, pindel, varscan2
- GSE1 | c.940T>G p.S314A | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.112); catalogued as COSV99495891; called by muse, mutect2, varscan2
- GTF2E2 | c.846G>T p.K282N | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV100577047; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs782372196, COSV100736378; called by mutect2, varscan2
- GUCY1A2 | c.487+2T>C p.X163_splice | Splice Site (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99972145; called by muse, mutect2, varscan2
- GYG1 | c.746G>T p.W249L | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56049254; called by muse, mutect2, varscan2
- H3-4 | c.35C>T p.T12M | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs1410959088, COSV64210722; called by muse, mutect2, varscan2
- H3C6 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as rs202067024, COSV64519438; called by muse, mutect2, varscan2
- H3C8 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.017); catalogued as COSV100009932, COSV59953520; called by muse, mutect2, varscan2
- HAS3 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs1255844667, COSV54706810; called by muse, mutect2, varscan2
- HCK | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as COSV99393535; called by muse, mutect2, varscan2
- HEATR5B | c.6214del p.*2072Nfs*3 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs1315552549, COSV51848615; called by mutect2, varscan2
- HEATR5B | c.5173C>T p.R1725W | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs145019222; called by muse, mutect2, varscan2
- HERC2 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.493); catalogued as rs765482113, COSV99869875; called by muse, mutect2, varscan2
- HIF3A | c.26+2T>C p.X9_splice | Splice Site (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99355394; called by muse, mutect2, varscan2
- HIP1R | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747647256, COSV99458047; called by muse, mutect2, varscan2
- HIPK3 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as rs755320304, COSV100305238; called by muse, mutect2, varscan2
- HIRIP3 | c.37A>G p.S13G | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.162); catalogued as COSV99662754; called by muse, mutect2, varscan2
- HKDC1 | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1201295597, COSV63577693; called by muse, mutect2, varscan2
- HMCN1 | c.7628C>A p.P2543Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV99622308; called by muse, mutect2, varscan2
- HMCN1 | c.13453C>T p.R4485W | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781672541, COSV54900578; called by muse, mutect2, varscan2
- HMGB4 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.442); catalogued as rs769598918, COSV53907834; called by muse, mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 28/48 reads (58%) | catalogued as rs755016625; called by mutect2, varscan2
- HOOK1 | c.863G>T p.R288M | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100968938; called by muse, mutect2, varscan2
- HOXA3 | c.904del p.Q302Rfs*74 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs761726531; called by mutect2, pindel, varscan2
- HPD | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 26/108 reads (24%) | catalogued as rs765923504, COSV56643393; called by muse, mutect2, varscan2
- HS3ST3B1 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62906710; called by muse, mutect2, varscan2
- HSF1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs369608182; called by muse, mutect2
- HSPA1A | c.1823G>A p.S608N | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.297); catalogued as COSV100989311; called by muse, mutect2, varscan2
- HTR1B | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199934430, COSV64051046; called by muse, mutect2, varscan2
- HTR2B | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.401); catalogued as COSV99295104; called by muse, mutect2, varscan2
- ICA1 | c.1348T>G p.S450A | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.127); catalogued as COSV99654614; called by muse, mutect2, varscan2
- ICAM3 | c.668del p.P223Rfs*21 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as rs759151580; called by mutect2, pindel
- ICE1 | c.5291G>A p.R1764Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1260261209, COSV56825791; called by muse, mutect2, varscan2
- IDE | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1297745019, COSV99793686; called by muse, mutect2, varscan2
- IFNA16 | c.166A>G p.R56G | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101207046; called by muse, mutect2, varscan2
- IFNA8 | c.217A>G p.K73E | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as COSV101206869; called by muse, mutect2, varscan2
- IFNGR2 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV51639949; called by muse, mutect2, varscan2
- IFRD1 | c.916dup p.Y306Lfs*2 | Frame Shift Ins (INS) | VAF 16/59 reads (27%) | catalogued as rs979653918; called by mutect2, varscan2
- IGHG1 | c.383del p.P128Qfs*8 | Frame Shift Del (DEL) | VAF 31/156 reads (20%) | catalogued as rs1567316764; called by mutect2, pindel, varscan2
- IGLV3-25 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs377042516; called by muse, mutect2, varscan2
- IGSF10 | c.1967dup p.L656Ffs*18 | Frame Shift Ins (INS) | VAF 18/83 reads (22%) | catalogued as rs1560178211; called by mutect2, pindel, varscan2
- IGSF10 | c.382C>A p.L128I | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99176526; called by muse, mutect2, varscan2
- IGSF9 | c.3328C>T p.R1110W (on ENST00000368094 / NM_001135050.2; = p.R1094W on NM_020789.4) | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.727); catalogued as rs775565374, COSV100230918; called by muse, mutect2, varscan2
- IKZF1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV58789842; called by muse, mutect2, varscan2
- IL11RA | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as COSV99426375; called by muse, mutect2, varscan2
- IL12RB1 | c.1626G>T p.Q542H | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV101651853; called by muse, mutect2, varscan2
- IL36A | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV99382001; called by muse, mutect2, varscan2
- IMPG2 | c.1610C>G p.T537S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV99514477; called by muse, mutect2, varscan2
- IQCN | c.703del p.L235Wfs*17 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | catalogued as rs748291022, COSV66574173; called by mutect2, pindel, varscan2
- IQSEC2 | c.3079del p.L1027Sfs*75 (on ENST00000642864 / NM_001111125.3; = p.L822Sfs*75 on NM_015075.2) | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as COSV64725845; called by mutect2, pindel, varscan2
- IRS4 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100929386, COSV100929724; called by muse, mutect2, varscan2
- ISG20 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs747830918, COSV60143187; called by muse, mutect2, varscan2
- ITFG1 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100278196; called by muse, mutect2, varscan2
- ITGA3 | c.1613T>G p.V538G | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.491); catalogued as COSV99143181; called by muse, mutect2, varscan2
- ITPR2 | c.7250del p.L2417* | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | catalogued as rs1288961144; called by mutect2, varscan2
- IVD | c.487G>A p.G163R (on ENST00000651168; = p.G160R on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/309 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285675428, COSV51098805; called by muse, mutect2, varscan2
- KANK1 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV100619338; called by muse, mutect2, varscan2
- KAT7 | c.1133A>T p.Q378L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1211760137, COSV99371535; called by muse, mutect2, varscan2
- KCNA3 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs764269530, COSV100871182; called by muse, mutect2, varscan2
- KCNAB1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as rs780117292, COSV67485191; called by muse, mutect2, varscan2
- KCNH6 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs200388894, COSV59005511; called by muse, varscan2
- KCNJ16 | c.397G>T p.G133* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99387817; called by muse, mutect2, varscan2
- KCNK10 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs144714447; called by muse, mutect2, varscan2
- KCNMA1 | c.2306del p.K769Sfs*17 (on ENST00000286628 / NM_001161352.2; = p.K711Sfs*17 on NM_002247.4) | Frame Shift Del (DEL) | VAF 38/69 reads (55%) | catalogued as rs771351714; called by mutect2, varscan2
- KCTD13 | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100441944; called by muse, mutect2, varscan2
- KCTD20 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771944488, COSV99535685; called by muse, mutect2, varscan2
- KDM5B | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1282352157, COSV52507353; called by muse, mutect2, varscan2
- KDM6B | c.3551del p.P1184Lfs*31 | Frame Shift Del (DEL) | VAF 27/255 reads (11%) | catalogued as COSV99642676; called by mutect2, pindel, varscan2
- KDM6B | c.4737+2T>C p.X1579_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99640533; called by muse, mutect2, varscan2
- KERA | c.851T>G p.L284R | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99899261; called by muse, mutect2, varscan2
- KHDC4 | c.1013-2A>G p.X338_splice | Splice Site (SNP) | VAF 33/88 reads (38%) | catalogued as COSV100850748; called by muse, mutect2, varscan2
- KIAA0100 | c.5503A>T p.M1835L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.056); catalogued as COSV101197181, COSV66490429; called by muse, mutect2, varscan2
- KIAA1522 | c.211C>A p.R71S (on ENST00000373480 / NM_001198972.2; = p.R130S on NM_020888.3) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99614019; called by muse, mutect2, varscan2
- KIF21A | c.2148del p.V717Lfs*12 (on ENST00000361418 / NM_001378440.1; = p.V704Lfs*12 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as rs1193021160; called by mutect2, pindel, varscan2
- KIF24 | c.3997G>A p.E1333K | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV99902717; called by muse, mutect2, varscan2
- KIF26A | c.3805del p.R1269Gfs*7 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | catalogued as rs1458694083, COSV59464465; called by mutect2, pindel, varscan2
- KIF2B | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.107); catalogued as rs371085430, COSV52127441; called by muse, mutect2, varscan2
- KIRREL1 | c.1009del p.L337Sfs*14 | Frame Shift Del (DEL) | VAF 21/102 reads (21%) | catalogued as rs754171400, COSV63285253; called by pindel, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 28/121 reads (23%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KLHDC7A | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101272688; called by muse, mutect2, varscan2
- KLHL1 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.376); catalogued as rs1335828954, COSV100916833; called by muse, mutect2, varscan2
- KLHL32 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs779287994, COSV65111498; called by muse, mutect2, varscan2
- KLHL6 | c.1826C>T p.T609I | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100384180; called by muse, mutect2, varscan2
- KLHL6 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as rs535540527, COSV58065544; called by muse, mutect2, varscan2
- KLRC4 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.962); catalogued as rs571344592, COSV99062141; called by muse, mutect2, varscan2
- KMT2C | c.8525del p.N2842Mfs*21 | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | catalogued as rs1248944002; called by pindel, varscan2
- KNL1 | c.4934G>T p.R1645I (on ENST00000346991 / NM_170589.5; = p.R1619I on NM_144508.5) | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV100705737; called by muse, mutect2, varscan2
- KRT18 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV101183940; called by muse, mutect2, varscan2
- KRT2 | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs760110296, COSV100548250; called by muse, mutect2, varscan2
- KRTAP10-9 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100551325; called by muse, mutect2, varscan2
- KY | c.1595A>G p.K532R | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.32); catalogued as COSV101414927; called by muse, mutect2, varscan2
- KY | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs915639571, COSV101414928; called by muse, mutect2
- LAD1 | c.1274G>A p.G425D | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV100943754; called by muse, mutect2, varscan2
- LAD1 | c.976del p.A326Lfs*18 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as COSV66213139; called by mutect2, pindel, varscan2
- LAMA1 | c.7741G>A p.G2581R | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV101054487, COSV67540048; called by muse, mutect2, varscan2
- LAMA1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200844421, COSV67539030; called by muse, mutect2, varscan2
- LATS2 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1217575272, COSV66880866; called by muse, mutect2
- LCE2A | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs201971844; called by muse, mutect2, varscan2
- LCN6 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1377705134, COSV100366301; called by muse, mutect2, varscan2
- LGALS9 | c.835C>A p.R279S (on ENST00000395473 / NM_009587.3; = p.R247S on NM_002308.4) | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100119338, COSV56348203; called by muse, mutect2, varscan2
- LHCGR | c.864A>C p.K288N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs376857065; called by muse, mutect2, varscan2
- LILRA6 | c.200A>G p.E67G | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.199); catalogued as COSV99556837; called by muse, mutect2, varscan2
- LIPF | c.1163A>G p.D388G | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV99490063; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs780042765; called by mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 23/83 reads (28%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMBRD1 | c.223A>G p.K75E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100992396; called by muse, mutect2, varscan2
- LRGUK | c.1085A>C p.K362T | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99603603; called by muse, mutect2, varscan2
- LRP1 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as rs1555182239, COSV99673804; called by muse, mutect2, varscan2
- LRRC47 | c.1400G>A p.S467N | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100989249; called by muse, mutect2, varscan2
- LRRTM1 | c.1016A>G p.N339S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99701536; called by muse, mutect2, varscan2
- LTBP2 | c.1972C>T p.R658W | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs180947562, COSV56215038; called by muse, mutect2, varscan2
- LTBP2 | c.749G>A p.S250N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV99999421; called by muse, mutect2, varscan2
- LZTS2 | c.303del p.S102Afs*41 | Frame Shift Del (DEL) | VAF 22/73 reads (30%) | catalogued as rs1460451498; called by mutect2, varscan2
- MADD | c.1960A>G p.T654A | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100210810; called by muse, mutect2, varscan2
- MAF | c.857T>C p.V286A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.759); catalogued as COSV100391563; called by muse, mutect2, varscan2
- MAGEB1 | c.908A>G p.H303R | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs750463044, COSV100974783; called by muse, mutect2, varscan2
- MAGI2 | c.1202C>G p.P401R | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100831762, COSV100836338; called by muse, mutect2, varscan2
- MAN1A1 | c.1190G>T p.S397I | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.726); catalogued as COSV100870558; called by muse, mutect2, varscan2
- MAN2B2 | c.2243A>G p.N748S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.078); catalogued as COSV99576850; called by muse, mutect2, varscan2
- MAP10 | c.1448del p.K483Sfs*3 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | catalogued as rs758304568; called by mutect2, pindel, varscan2
- MAP2K7 | c.875del p.P292Qfs*119 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | catalogued as COSV67608111; called by mutect2, pindel, varscan2
- MAP3K19 | c.3406G>A p.V1136M | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1406193709, COSV100207832; called by muse, mutect2, varscan2
- MAP3K9 | c.2996C>T p.A999V (on ENST00000554752 / NM_001284230.1; = p.A1013V on NM_033141.4) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV101173406; called by muse, mutect2, varscan2
- MAPT | c.1921C>T p.P641S (on ENST00000262410 / NM_001377265.1; = p.P249S on NM_005910.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99289503; called by muse, mutect2
- MARCHF7 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99373410; called by muse, mutect2, varscan2
- MAST2 | c.2178dup p.G727Wfs*14 | Frame Shift Ins (INS) | VAF 52/196 reads (27%) | catalogued as rs1204109224; called by mutect2, varscan2
- MAST3 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1257587796, COSV99444036; called by muse, mutect2, varscan2
- MAST3 | c.2983G>A p.A995T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99444040; called by muse, mutect2
- MASTL | c.1390del p.T464Lfs*3 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs1355602467; called by mutect2, pindel, varscan2
- MBD5 | c.2157T>A p.S719R | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV101289876; called by muse, mutect2, varscan2
- MCEE | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99730899; called by muse, mutect2, varscan2
- MCM6 | c.936del p.E314Sfs*16 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | catalogued as rs747148219; called by mutect2, pindel, varscan2
- MCTP2 | c.1505T>C p.L502P | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as rs1399264342, COSV100537111; called by muse, mutect2, varscan2
- MDN1 | c.3818G>A p.R1273H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101020650, COSV65517441; called by muse, mutect2, varscan2
- MED16 | c.130C>A p.L44I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.196); catalogued as COSV99514970; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs745558596; called by mutect2, varscan2
- MEN1 | c.1234C>A p.P412T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV99580040; called by muse, mutect2, varscan2
- MFSD14B | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100942548; called by muse, mutect2, varscan2
- MGAM | c.1879G>T p.G627* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV101527331; called by muse, mutect2, varscan2
- MGAT4C | c.114del p.F38Lfs*2 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as rs1268226422; called by mutect2, pindel, varscan2
- MGAT5B | c.1627del p.L543Wfs*71 (on ENST00000569840 / NM_001199172.2; = p.L541Wfs*71 on NM_144677.3) | Frame Shift Del (DEL) | VAF 37/137 reads (27%) | catalogued as rs778939334; called by mutect2, pindel, varscan2
- MIA | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99648115; called by muse, mutect2
- MICB | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.095); catalogued as COSV99357270; called by muse, mutect2, varscan2
- MIER2 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs146065929; called by muse, mutect2
- MIIP | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.912); catalogued as COSV99337316; called by muse, mutect2
- MINDY3 | c.1276C>T p.Q426* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as COSV53217763; called by muse, mutect2, varscan2
- MIS18BP1 | c.2649G>T p.K883N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV60371354; called by muse, mutect2, varscan2
- MKX | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.766); catalogued as rs1291118259, COSV101008462; called by muse, mutect2, varscan2
- MLH3 | c.2648C>T p.S883F | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.365); catalogued as COSV99469351; called by muse, mutect2, varscan2
- MLH3 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs751375245, COSV53136067; called by muse, mutect2, varscan2
- MLIP | c.653T>C p.I218T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99228117; called by muse, mutect2, varscan2
- MLPH | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs183148581, COSV99221595; called by muse, mutect2, varscan2
- MOCS1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs567945725, COSV100418331, COSV100418487; called by muse, mutect2, varscan2
- MRGPRD | c.940G>A p.V314M | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs774928635, COSV58423415; called by muse, mutect2, varscan2
- MRI1 | c.548-1G>T p.X183_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99237089; called by muse, mutect2, varscan2
- MROH2B | c.3277C>T p.P1093S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.464); catalogued as COSV101270425; called by muse, mutect2, varscan2
- MRPL55 | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99686696; called by muse, mutect2, varscan2
- MST1R | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs781591594, COSV56568214; called by muse, mutect2, varscan2
- MTA1 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV100494817; called by muse, mutect2, varscan2
- MTMR4 | c.3222G>T p.K1074N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.477); catalogued as COSV100050661; called by muse, mutect2, varscan2
- MUC1 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.436); catalogued as COSV58115972; called by muse, mutect2, varscan2
- MUC5AC | c.969del p.L324Cfs*137 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | catalogued as rs1227165697; called by mutect2, pindel, varscan2
- MUC5B | c.11215G>A p.A3739T | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.052); catalogued as COSV101499939; called by muse, mutect2, varscan2
- MVP | c.2266-2A>G p.X756_splice | Splice Site (SNP) | VAF 31/120 reads (26%) | catalogued as COSV100651440; called by muse, mutect2, varscan2
- MXRA5 | c.2651T>C p.L884P | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99475338; called by muse, mutect2, varscan2
- MYH13 | c.352T>C p.Y118H | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99351626; called by muse, mutect2, varscan2
- MYH2 | c.351C>A p.T117= | Splice Region (SNP) | VAF 27/99 reads (27%) | catalogued as COSV99818984; called by muse, mutect2, varscan2
- MYH8 | c.4100C>T p.A1367V | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.4); catalogued as COSV101238045; called by muse, mutect2, varscan2
- MYLIP | c.279G>A p.R93= | Splice Region (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100785898; called by muse, mutect2, varscan2
- MYLK | c.5243C>T p.T1748M | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60622652; called by muse, mutect2, varscan2
- MYO15A | c.1120G>C p.V374L | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.015); catalogued as COSV99230631; called by muse, mutect2, varscan2
- MYO15A | c.2873del p.P958Lfs*28 | Frame Shift Del (DEL) | VAF 4/17 reads (24%) | catalogued as rs1217492313; called by mutect2, varscan2
- MYO15A | c.4109G>A p.R1370H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771676248, COSV52757440, COSV99230634; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO5A | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as COSV100697165; called by muse, mutect2, varscan2
- MYO6 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757665143, COSV64121213; called by muse, mutect2, varscan2
- MYO7B | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs370941935, COSV101267792; called by muse, varscan2
- MYO7B | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376693425, COSV67349974; called by muse, mutect2, varscan2
- MYORG | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as rs1487181829, COSV52627518; called by muse, mutect2, varscan2
- MYORG | c.810del p.A271Pfs*9 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs1273605193; called by mutect2, pindel, varscan2
- NAA25 | c.1985dup p.S663Qfs*11 | Frame Shift Ins (INS) | VAF 45/162 reads (28%) | catalogued as rs1324340510; called by mutect2, varscan2
- NBAS | c.5747A>G p.E1916G | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV99866417; called by muse, mutect2, varscan2
- NBEAL2 | c.6952C>T p.R2318W | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as rs1328163964, COSV99433936; called by muse, mutect2, varscan2
- NCAPD3 | c.2725del p.Q909Rfs*10 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | catalogued as rs770284236; called by mutect2, pindel, varscan2
- NCAPH2 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.096); catalogued as COSV100237777; called by muse, mutect2, varscan2
- NCOA1 | c.3286C>T p.Q1096* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99944875; called by muse, mutect2, varscan2
- NCOA2 | c.1995_1998del p.N665Kfs*41 | Frame Shift Del (DEL) | VAF 36/134 reads (27%) | catalogued as rs1307457412; called by pindel, varscan2
- NEGR1 | c.1031G>T p.S344I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as COSV100159958; called by muse, mutect2, varscan2
- NELFA | c.1154C>T p.A385V (on ENST00000542778; = p.A374V on NM_005663.5) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.207); catalogued as rs375949981; called by muse, mutect2, varscan2
- NELFB | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as rs752643955, COSV58025294; called by muse, mutect2, varscan2
- NEPRO | c.837del p.A280Lfs*4 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs1233131890, COSV100075132; called by mutect2, pindel, varscan2
- NEXMIF | c.4193T>A p.V1398E | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.075); catalogued as COSV99279259; called by muse, mutect2, varscan2
- NFASC | c.905G>A p.R302H (on ENST00000339876 / NM_001378329.1; = p.R313H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs766397794, COSV100362403; called by muse, mutect2, varscan2
- NFATC1 | c.2374C>T p.Q792* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99500188; called by muse, mutect2, varscan2
- NFE2L2 | c.594G>T p.Q198H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV101229271; called by muse, mutect2, varscan2
- NHLRC1 | c.612del p.F204Lfs*28 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | catalogued as rs1171412241, CD054388; called by mutect2, pindel, varscan2
- NIP7 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs1164294866, COSV99650565; called by muse, mutect2, varscan2
- NISCH | c.614A>G p.Q205R | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100617037; called by muse, mutect2, varscan2
- NKIRAS2 | c.157del p.V53Cfs*78 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as COSV100288809; called by mutect2, pindel, varscan2
- NLGN4X | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as COSV99319383; called by muse, mutect2, varscan2
- NLRP12 | c.808A>G p.S270G | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100144670; called by muse, mutect2, varscan2
- NMRK1 | c.476A>G p.Q159R | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1387897964, COSV100737815; called by muse, mutect2, varscan2
- NOA1 | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.241); catalogued as COSV99950380; called by muse, mutect2, varscan2
- NOL6 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV99954320; called by muse, mutect2, varscan2
- NOTCH1 | c.2909C>T p.T970I | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs571425395, COSV53083989; called by muse, mutect2, varscan2
- NOTCH4 | c.4937G>A p.R1646Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs748941744, COSV100900255; called by muse, mutect2, varscan2
- NPEPPS | c.2176C>T p.R726C | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs762616490, COSV100443343; called by muse, mutect2, varscan2
- NPLOC4 | c.1400C>T p.S467L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.131); catalogued as rs1386982218, COSV58621174; called by muse, mutect2, varscan2
- NPPC | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV99776610; called by muse, mutect2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs774343392; called by mutect2, varscan2
- NR3C2 | c.1618A>G p.R540G | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100678545; called by muse, mutect2, varscan2
- NR4A2 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100276865; called by muse, mutect2, varscan2
- NRDC | c.3488T>C p.L1163P | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100542774; called by muse, mutect2, varscan2
- NRXN2 | c.3728G>A p.S1243N | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99631988; called by muse, mutect2, varscan2
- NT5C1B | c.323G>A p.R108Q (on ENST00000359846 / NM_001199086.2; = p.R48Q on NM_033253.4) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs142174343, COSV100410115; called by muse, mutect2, varscan2
- NT5C2 | c.516dup p.T173Yfs*2 | Frame Shift Ins (INS) | VAF 10/45 reads (22%) | catalogued as rs1348834719; called by mutect2, varscan2
- NTN3 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs746365729, COSV99564574; called by muse, mutect2, varscan2
- NTNG1 | c.1285C>T p.H429Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV64271797; called by muse, mutect2, varscan2
- NTNG2 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765705117, COSV100647173; called by mutect2, varscan2
- NUP88 | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV56707322; called by muse, mutect2, varscan2
- NYNRIN | c.4090C>T p.R1364C | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as rs775248149, COSV101230473; called by muse, mutect2, varscan2
- OBSCN | c.22507del p.L7503Wfs*19 | Frame Shift Del (DEL) | VAF 46/172 reads (27%) | catalogued as rs755333505; called by mutect2, pindel, varscan2
- OCA2 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as rs370353320; called by muse, mutect2, varscan2
- OCIAD1 | c.696dup p.E233Rfs*13 | Frame Shift Ins (INS) | VAF 18/64 reads (28%) | catalogued as rs768679897; called by mutect2, varscan2
- OLFM4 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.186); catalogued as COSV99524134; called by muse, mutect2, varscan2
- OR10Z1 | c.695A>C p.E232A | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV100778910; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | catalogued as rs761899382; called by mutect2, varscan2
- OR1K1 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.401); catalogued as rs1408265710, COSV99474131; called by muse, mutect2, varscan2
- OR2AG1 | c.100C>A p.L34I | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.694); catalogued as COSV56626813; called by muse, mutect2, varscan2
- OR2M4 | c.820G>C p.V274L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as COSV100140905; called by muse, mutect2, varscan2
- OR4C16 | c.363T>G p.Y121* | Nonsense Mutation (SNP) | VAF 30/139 reads (22%) | catalogued as COSV100113743; called by muse, mutect2, varscan2
- OR4D2 | c.795C>A p.F265L | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.168); catalogued as COSV101613831, COSV101613872; called by muse, mutect2, varscan2
- OR51E2 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101211291; called by muse, mutect2, varscan2
- OR51Q1 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100332770; called by muse, mutect2, varscan2
- OR8U1 | c.910dup p.I304Nfs*5 | Frame Shift Ins (INS) | VAF 12/76 reads (16%) | catalogued as rs1235208538; called by pindel, varscan2
- OR9Q2 | c.424T>C p.W142R | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100285271; called by muse, mutect2, varscan2
- OS9 | c.1624C>T p.R542W | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs752513773, COSV99232405; called by muse, mutect2, varscan2
- P2RY8 | c.982G>T p.A328S | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as rs765148420, COSV101183919, COSV67177482; called by muse, mutect2, varscan2
- PABPN1L | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs780172548, COSV56351818; called by muse, mutect2, varscan2
- PACS1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.828); catalogued as rs1162091567, COSV100269418; called by muse, mutect2, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 54/241 reads (22%) | catalogued as rs751755759; called by mutect2, pindel, varscan2
- PAPPA2 | c.2426A>G p.Y809C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868793697, COSV100866403; called by muse, mutect2, varscan2
- PARP16 | c.932C>A p.S311Y | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99975170; called by muse, mutect2, varscan2
- PAX1 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); catalogued as COSV101270166; called by muse, mutect2, varscan2
- PAX8 | c.1109C>T p.T370M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs377351599; called by muse, varscan2
- PC | c.2790G>T p.E930D | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100546916; called by muse, mutect2, varscan2
- PCDH10 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs1210216695, COSV99992585, COSV99994753; called by muse, mutect2, varscan2
- PCDH18 | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100786899; called by muse, mutect2, varscan2
- PCDHA2 | c.2295del p.K766Rfs*29 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | catalogued as rs558931090, COSV65368078; called by mutect2, pindel, varscan2
- PCDHA5 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.163); catalogued as COSV100972033; called by muse, mutect2, varscan2
- PCDHA8 | c.304T>C p.C102R | Missense Mutation (SNP) | VAF 60/261 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1425270500, COSV100970301; called by muse, mutect2, varscan2
- PCDHB10 | c.1829C>T p.T610M | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1554284391, COSV99503483; called by muse, mutect2, varscan2
- PCDHB6 | c.1682A>G p.Y561C | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50720831; called by muse, varscan2
- PCDHGA10 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.562); catalogued as COSV99528144; called by muse, mutect2, varscan2
- PCNT | c.1232A>G p.H411R | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100854929, COSV64028322; called by muse, mutect2, varscan2
- PCNT | c.6797C>T p.T2266I | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV100854930; called by muse, mutect2, varscan2
- PCNX4 | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.552); catalogued as rs376697584; called by muse, mutect2, varscan2
- PDE6A | c.2549del p.G850Vfs*42 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as rs780549355; called by mutect2, pindel, varscan2
- PDGFB | c.657del p.K220Rfs*16 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs1274478632; called by mutect2, pindel, varscan2
- PDSS1 | c.178C>A p.L60I | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.115); catalogued as COSV100873475; called by muse, mutect2, varscan2
- PGAP1 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100697928; called by muse, mutect2, varscan2
- PHACTR2 | c.1125G>T p.W375C | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.338); catalogued as COSV59853261, COSV99990813; called by muse, mutect2
- PHF10 | c.1070G>A p.G357D | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.389); catalogued as COSV100179028; called by muse, mutect2, varscan2
- PHF21A | c.1820G>A p.R607Q (on ENST00000418153 / NM_001101802.3; = p.R561Q on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as rs375495711, COSV57651732; called by muse, mutect2, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PHGDH | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV101024990; called by muse, mutect2, varscan2
- PHKA1 | c.2411C>T p.A804V | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100262262; called by muse, mutect2, varscan2
- PHLPP2 | c.1192A>G p.M398V | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV100673435; called by muse, mutect2, varscan2
- PIAS2 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as COSV100244843, COSV61342239; called by muse, mutect2, varscan2
- PIGG | c.1647G>T p.E549D (on ENST00000453061 / NM_001127178.3; = p.E541D on NM_017733.4) | Missense Mutation (SNP) | VAF 98/382 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV99573477; called by muse, mutect2, varscan2
- PIK3R4 | c.3332T>C p.V1111A | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100768111; called by muse, mutect2, varscan2
- PITPNM1 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs368212702; called by muse, mutect2, varscan2
- PKD1 | c.9239C>T p.T3080I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs1322954391; called by muse, mutect2, varscan2
- PKD1L2 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs867314211, COSV100215946; called by muse, varscan2
- PKHD1 | c.5707G>A p.V1903I | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs753639079, COSV61884120, COSV61891662; called by muse, mutect2, varscan2
- PLA2G2D | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as rs201515699, COSV100907987; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 35/144 reads (24%) | catalogued as rs745860467; called by mutect2, varscan2
- PLCD1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.982); catalogued as rs780533634, COSV52187777; called by muse, mutect2, varscan2
- PLCE1 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99592927; called by muse, mutect2, varscan2
- PLCG1 | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764393595, COSV54821675; called by muse, mutect2, varscan2
- PLCG2 | c.2739G>T p.K913N | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV100841990, COSV63868021; called by muse, mutect2, varscan2
- PLEKHH1 | c.3535C>T p.R1179C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs200119528; called by muse, mutect2, varscan2
- PLEKHH3 | c.574del p.V192Wfs*6 | Frame Shift Del (DEL) | VAF 13/79 reads (16%) | catalogued as rs778393033; called by pindel, varscan2*
- PLPPR1 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV100882861; called by muse, mutect2, varscan2
- PLXNB1 | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.657); catalogued as rs1413574464, COSV99602001; called by muse, mutect2, varscan2
- PLXNC1 | c.2321T>C p.M774T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99312240; called by muse, mutect2, varscan2
- PML | c.1682G>A p.S561N | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99166597; called by muse, mutect2, varscan2
- POC1B | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100543986; called by muse, mutect2, varscan2
- POLE | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs749194160, COSV100264977; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR2B | c.1406T>C p.V469A | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100107699; called by muse, mutect2, varscan2
- POLR2D | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99760901; called by muse, mutect2, varscan2
- POLR3E | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100241823; called by muse, mutect2, varscan2
- POMGNT2 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.206); catalogued as rs554958082, COSV100767874; called by muse, mutect2
- PON2 | c.195del p.F65Lfs*5 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | catalogued as rs1201102139; called by mutect2, pindel, varscan2
- POP4 | c.602A>G p.Q201R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV99694440; called by muse, mutect2, varscan2
- POTEE | c.2766C>A p.D922E | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); catalogued as COSV100386888; called by muse, mutect2
- PPDPFL | c.215A>G p.K72R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV100293003; called by muse, mutect2, varscan2
- PPM1G | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100084791; called by muse, mutect2, varscan2
- PPM1J | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs113935705; called by muse, mutect2, varscan2
- PPP1R10 | c.930del p.V311Yfs*79 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs746108087; called by mutect2, varscan2
- PPP1R14C | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs755713386, COSV100744773; called by muse, mutect2, varscan2
- PPP4R3B | c.921G>T p.Q307H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99701246; called by muse, mutect2, varscan2
- PRAMEF12 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769755107, COSV63214663; called by muse, mutect2, varscan2
- PRB2 | c.1165C>A p.Q389K | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV101231352; called by muse, mutect2
- PRG4 | c.3553A>G p.I1185V | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100798067; called by muse, mutect2, varscan2
- PRKACB | c.145del p.T49Pfs*13 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as rs1291568884; called by mutect2, varscan2
- PRKAG2 | c.593del p.P198Rfs*56 | Frame Shift Del (DEL) | VAF 15/75 reads (20%) | catalogued as COSV55232567; called by mutect2, pindel, varscan2
- PRKCE | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100076168; called by muse, mutect2, varscan2
- PRMT1 | c.1083G>T p.E361D | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs769054141, COSV99773139; called by muse, mutect2, varscan2
- PRORP | c.257del p.L86* | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs760446387; called by mutect2, varscan2
- PROX2 | c.599T>C p.L200P | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV101507779; called by muse, mutect2, varscan2
- PRPSAP2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs764385412, COSV99264261; called by muse, mutect2, varscan2
- PRR16 | c.98T>C p.I33T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101086028; called by muse, mutect2
- PRTG | c.2228G>T p.R743M | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as COSV66837837; called by muse, mutect2, varscan2
- PRX | c.3253del p.E1085Kfs*42 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | catalogued as rs758500214; called by mutect2, pindel, varscan2
- PTDSS1 | c.586T>C p.W196R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100428383; called by muse, mutect2, varscan2
- PTGS1 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753219685, COSV56293178; called by muse, mutect2, varscan2
- PTPN3 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs1465045994, COSV99355236; called by muse, mutect2, varscan2
- PTPN3 | c.413G>T p.R138M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99355238; called by muse, mutect2, varscan2
- PTPRT | c.3224del p.P1075Rfs*6 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as rs1568940954, COSV62005004; called by mutect2, pindel, varscan2
- RAB6A | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs771441560, COSV100154747; called by muse, mutect2, varscan2
- RAI14 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as COSV54296636; called by muse, mutect2, varscan2
- RALA | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.107); catalogued as rs772097468, COSV50048743; called by muse, varscan2
- RALGAPA2 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99173059; called by muse, mutect2, varscan2
- RANBP17 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101205946; called by muse, mutect2, varscan2
- RAPGEF3 | c.2392C>T p.R798W (on ENST00000389212; = p.R756W on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs753781665, COSV99405609; called by muse, mutect2, varscan2
- RASA1 | c.1475del p.N492Ifs*6 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | catalogued as COSV99169778; called by mutect2, pindel, varscan2
- RBM15B | c.1972C>T p.H658Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.425); catalogued as COSV100081850; called by muse, mutect2, varscan2
- RBM6 | c.2629G>A p.V877I | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.979); catalogued as rs1175509612, COSV56481503; called by muse, mutect2, varscan2
- RBPMS2 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100264698; called by muse, mutect2
- RELN | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774401106, COSV100631892; called by muse, mutect2, varscan2
- RERE | c.3495G>T p.E1165D | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.212); catalogued as COSV100555049; called by muse, mutect2, varscan2
- RET | c.2763A>T p.E921D | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV100391903; called by muse, mutect2, varscan2
- RFXAP | c.703del p.R235Dfs*5 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | catalogued as rs1566320519; called by mutect2, pindel, varscan2
- RHOXF2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.829); catalogued as rs1309289784; called by mutect2, varscan2
- RIMBP3 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1487481706; called by muse, mutect2
- RIMS1 | c.2873G>A p.R958H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373238402, COSV99327156; called by muse, mutect2, varscan2
- RIMS1 | c.3605C>A p.T1202N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99322866; called by muse, mutect2, varscan2
- RIN3 | c.1064G>T p.R355M | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as COSV99378195; called by muse, mutect2, varscan2
- RMDN3 | c.1156del p.T386Lfs*22 | Frame Shift Del (DEL) | VAF 23/68 reads (34%) | catalogued as rs745408248; called by mutect2, varscan2
- RNF217 | c.387del p.G130Afs*66 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs757325037; called by mutect2, pindel, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 64/114 reads (56%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as rs752898741; called by mutect2, varscan2
- ROCK1 | c.3532C>T p.P1178S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.058); catalogued as COSV101296201; called by muse, mutect2, varscan2
- ROR1 | c.2164T>C p.Y722H | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1484670633, COSV100934759; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPRD2 | c.2463C>A p.F821L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100954807, COSV100955377; called by muse, mutect2, varscan2
- RPS13 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as COSV57181007; called by muse, mutect2
- RRBP1 | c.4127C>T p.T1376M (on ENST00000377813 / NM_001365613.2; = p.T943M on NM_004587.3) | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs184544168; called by muse, mutect2, varscan2
- RSPH1 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.075); catalogued as rs778123315, COSV52318357; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RTTN | c.5744del p.K1915Rfs*9 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as rs756606313; called by mutect2, varscan2
- RUNX2 | c.1283G>A p.G428D (on ENST00000371438; = p.G406D on NM_001015051.3) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100767023; called by muse, mutect2, varscan2
- SAGE1 | c.2463del p.I823Lfs*5 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as rs1556606789, COSV61011396, COSV61011613, COSV61011686; called by mutect2, varscan2
- SAMD9L | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.62); catalogued as rs776780720, COSV59085563; called by muse, mutect2, varscan2
- SARS1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99320828; called by muse, mutect2, varscan2
- SBNO2 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761289898, COSV100683894; called by muse, mutect2, varscan2
- SC5D | c.545T>C p.I182T | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV99872911; called by muse, mutect2, varscan2
- SCAF11 | c.4355T>C p.L1452P | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV101013998; called by muse, mutect2, varscan2
- SCUBE1 | c.2638G>A p.A880T | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100682625; called by muse, mutect2, varscan2
- SCUBE1 | c.1697A>G p.E566G | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100682628; called by muse, mutect2, varscan2
- SEC24B | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770989941, COSV54498557, COSV54502109; called by muse, mutect2, varscan2
- SEC24D | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as rs970771040, COSV99755167; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEC31A | c.143T>C p.L48S | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100306532; called by muse, mutect2
- SEMA3B | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57113913; called by muse, mutect2, varscan2
- SEMA6C | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.386); catalogued as COSV100500979; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as rs750651342; called by mutect2, varscan2
- SERINC3 | c.34A>G p.S12G | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV99667529; called by muse, mutect2, varscan2
- SETBP1 | c.786G>T p.K262N | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99951558; called by muse, mutect2
- SETBP1 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56313088, COSV56313647; called by muse, mutect2, varscan2
827 further variants in this file (482 protein-altering or splice-affecting, 312 silent, 33 other) are not listed here.
